Somatic mutation profile of tumor specimen TCGA-AO-A0JA-01A (aliquot TCGA-AO-A0JA-01A-11W-A071-09) from TCGA case TCGA-AO-A0JA, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 36.4 years (13,307 days).
Specimen TCGA-AO-A0JA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 999f0a32-30c2-466d-b3e4-6c0983ab248c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0JA-10A (Blood Derived Normal), aliquot TCGA-AO-A0JA-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba114d36-576f-429d-b6c1-e19349e74d2c

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 14, Silent 9, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.264T>A p.Y88* | Nonsense Mutation (SNP) | VAF 84/160 reads (53%) | catalogued as rs1554898056, CM1513159, COSV64289806; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CSMD1 | c.7517C>A p.S2506* (on ENST00000520002; = p.S2505* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV59283026, COSV59346180; called by muse, mutect2, varscan2
- CSMD1 | c.2626G>C p.D876H (on ENST00000520002; = p.D875H on NM_033225.6) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100141608, COSV59283046; called by muse, mutect2, varscan2
- EID3 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as COSV61597333; called by muse, mutect2, varscan2
- EXPH5 | c.2702C>T p.P901L | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV56198991; called by muse, mutect2, varscan2
- F5 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 116/543 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1347355575, COSV63120579, COSV63127262; called by muse, mutect2, varscan2
- IL18RAP | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV51823944; called by muse, mutect2, varscan2
- ITPR2 | c.4252G>A p.E1418K | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV101189941, COSV67264893; called by muse, mutect2, varscan2
- MAP3K15 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs755282207, COSV58826132; called by muse, mutect2, varscan2
- MORC4 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 98/303 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55239543; called by muse, mutect2, varscan2
- MUC5B | c.8552C>G p.S2851W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV71590090; called by muse, mutect2, varscan2
- MYLK | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60605014; called by muse, mutect2, varscan2
- NUMA1 | c.5501C>T p.S1834L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs141331520, COSV52619840; called by muse, mutect2, varscan2
- RAB39A | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.583); catalogued as COSV57694484; called by muse, mutect2, varscan2
- ZNF683 | c.1375C>A p.Q459K (on ENST00000403843; = p.Q439K on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV62873400; called by muse, mutect2, varscan2
- GPS2 | c.136_139del p.E46Nfs*16 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by pindel, varscan2
- LYSMD3 | c.306_318del p.F102Lfs*6 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | called by mutect2, pindel, varscan2
- NEU2 | c.717_727del p.H239Qfs*9 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- RLF | c.1464dup p.D489Rfs*3 | Frame Shift Ins (INS) | VAF 36/90 reads (40%) | called by mutect2, pindel, varscan2
- BMPR1B | c.997C>T p.L333= | Silent (SNP) | VAF 76/279 reads (27%) | catalogued as COSV52774885; called by muse, mutect2, varscan2
- CPT1A | c.447C>T p.I149= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV55752994; called by muse, mutect2, varscan2
- DNAH11 | c.8337G>T p.L2779= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV60940433; called by muse, mutect2, varscan2
- FLRT1 | c.123C>T p.L41= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs958881632, COSV99735850; called by muse, mutect2, varscan2
- IL1RL2 | c.378A>G p.P126= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as COSV99961002; called by muse, mutect2
- IZUMO2 | c.459G>A p.R153= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as COSV53229219; called by muse, mutect2, varscan2
- KNOP1 | c.807G>A p.K269= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99575313; called by muse, mutect2, varscan2
- OR7G1 | c.876G>A p.L292= | Silent (SNP) | VAF 73/238 reads (31%) | catalogued as COSV53317002; called by muse, mutect2, varscan2
- ZBED1 | c.348C>T p.H116= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs368610328, COSV100585936; called by muse, mutect2, varscan2
